Somatic mutation profile of tumor specimen MMRF_2286_1_BM_CD138pos (aliquot MMRF_2286_1_BM_CD138pos_T1_KHS5U_L11017) from MMRF case MMRF_2286, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.1 years (24,882 days).
Specimen MMRF_2286_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 231b488a-d058-4838-853d-3d9bf7d163bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2286_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2286_1_PB_Whole_C2_KHS5U_L11016; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d92a1927-e4a2-45d3-82ef-d22c721ef258

The open-access MAF lists 110 somatic variants for this specimen: 51 protein-altering or splice-affecting, 18 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, 3'UTR 19, Silent 18, Intron 12, 5'UTR 4, 5'Flank 3, Frame Shift Del 3, In Frame Del 3, Nonsense Mutation 2, RNA 2, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD22 | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs201744509; called by muse, mutect2, varscan2
- ARID1B | c.2210G>A p.R737Q | Missense Mutation (SNP) | VAF 109/207 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); catalogued as rs764402992; called by muse, mutect2, varscan2
- IGHV2-70 | c.287A>G p.K96R | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as rs138836314; called by muse, varscan2
- IGHV2-70D | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as rs1379651975; called by muse, varscan2
- IGHV2-70D | c.221G>A p.W74* | Nonsense Mutation (SNP) | VAF 30/187 reads (16%) | catalogued as rs1269771326; called by muse, varscan2
- IGKV1D-43 | c.253A>T p.S85C | Missense Mutation (SNP) | VAF 71/155 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1211114538; called by muse, mutect2, varscan2
- IGKV1D-8 | c.201G>C p.E67D | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs547296809; called by muse, varscan2
- IGLL5 | c.177C>G p.S59R | Missense Mutation (SNP) | VAF 16/16 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as rs569308745, COSV104440313, COSV73250973; called by muse, mutect2, varscan2
- IGLV3-1 | c.91G>C p.V31L | Missense Mutation (SNP) | VAF 68/69 reads (99%) | SIFT deleterious (0.04); PolyPhen benign (0.397); catalogued as rs773986506; called by muse, mutect2
- IGLV3-1 | c.251A>G p.N84S | Missense Mutation (SNP) | VAF 69/69 reads (100%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as rs373605544; called by muse, varscan2
- IGLV7-46 | c.275C>G p.A92G | Missense Mutation (SNP) | VAF 56/100 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.229); catalogued as rs1302682317; called by muse, mutect2
- ITGAM | c.2849G>A p.R950Q (on ENST00000648685 / NM_001145808.2; = p.R949Q on NM_000632.4) | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs1168842622, COSV54944663; called by muse, mutect2, varscan2
- KIAA1210 | c.1687G>C p.G563R | Missense Mutation (SNP) | VAF 139/273 reads (51%) | SIFT tolerated (0.57); PolyPhen benign (0.077); catalogued as COSV101273899; called by muse, mutect2, varscan2
- KLHL6 | c.208G>C p.A70P | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.403); catalogued as rs749942087, COSV58067504; called by muse, mutect2, varscan2
- LTBR | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as rs761530479; called by muse, mutect2, varscan2
- MYO1F | c.1562G>A p.R521Q | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1400523125, COSV100596798; called by muse, mutect2
- OR6B3 | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as rs754300392; called by muse, mutect2, varscan2
- RAB4B | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 79/179 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.098); catalogued as rs1202172147; called by muse, mutect2, varscan2
- RFTN1 | c.826+1G>A p.X276_splice | Splice Site (SNP) | VAF 40/106 reads (38%) | catalogued as rs199528537; called by muse, varscan2
- SLC4A3 | c.2218G>A p.V740M | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56096719; called by muse, mutect2, varscan2
- SREBF1 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs528968412; called by muse, mutect2, varscan2
- TIGD6 | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 123/253 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs749543017; called by muse, mutect2, varscan2
- UBTF | c.995G>A p.W332* | Nonsense Mutation (SNP) | VAF 35/70 reads (50%) | catalogued as rs1313771483; called by muse, mutect2, varscan2
- CCDC93 | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDH12 | c.1783G>A p.D595N | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DDX17 | c.431T>A p.L144Q | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- DOK7 | c.1426del p.E476Kfs*25 | Frame Shift Del (DEL) | VAF 33/102 reads (32%) | called by mutect2, pindel, varscan2
- EHMT1 | c.310_312dup p.A104dup | In Frame Ins (INS) | VAF 97/396 reads (24%) | called by mutect2, pindel, varscan2
- FAM160A2 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FAT1 | c.6709A>G p.N2237D | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- FOXB1 | c.799C>G p.P267A | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- HMCES | c.181A>G p.K61E | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.698); called by muse, varscan2
- IGHV2-70D | c.337A>C p.T113P | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, varscan2
- IGHV2-70D | c.323C>G p.P108R | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, varscan2
- IGHV2-70D | c.256A>G p.T86A | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, varscan2
- IL17RA | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 63/124 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- LBX2 | c.302A>C p.E101A (on ENST00000377566 / NM_001282430.2; = p.E97A on NM_001009812.2) | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MTMR2 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYC | c.793_795del p.V265del (on ENST00000377970; = p.V280del on NM_002467.6) | In Frame Del (DEL) | VAF 38/260 reads (15%) | called by pindel, varscan2
- MYO5C | c.1124_1126del p.N375_R376delinsS | In Frame Del (DEL) | VAF 46/143 reads (32%) | called by mutect2, pindel, varscan2
- OR52A5 | c.779_781del p.F260del | In Frame Del (DEL) | VAF 131/316 reads (41%) | called by pindel, varscan2
- PPP3CA | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.183); called by muse, mutect2
- PRICKLE3 | c.1289G>A p.R430K | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.051); called by muse, mutect2
- RFTN1 | c.763A>C p.S255R | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, varscan2
- RYR3 | c.13357G>A p.D4453N (on ENST00000389232; = p.D4454N on NM_001036.6) | Missense Mutation (SNP) | VAF 63/147 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SHTN1 | c.711G>C p.E237D | Missense Mutation (SNP) | VAF 69/153 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TAS2R16 | c.731T>G p.L244R | Missense Mutation (SNP) | VAF 94/198 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- TNS2 | c.1495C>G p.P499A (on ENST00000314250 / NM_170754.4; = p.P509A on NM_015319.2) | Missense Mutation (SNP) | VAF 70/138 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TOP3A | c.851A>G p.N284S | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRPC5 | c.1820_1821del p.T607Ifs*29 | Frame Shift Del (DEL) | VAF 18/143 reads (13%) | called by mutect2, pindel, varscan2
- TTN | c.25967_25970del p.Q8656Pfs*3 (on ENST00000591111; = p.Q7729Pfs*3 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/112 reads (11%) | called by mutect2, pindel, varscan2
- C5AR2 | c.645C>A p.A215= | Silent (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- DDC | c.510G>A p.A170= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs774547345, COSV63563798; called by muse, mutect2, varscan2
- EFCAB5 | c.2994G>A p.P998= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs1007100228, COSV57935960; called by muse, mutect2, varscan2
- IGHV5-51 | c.174G>A p.Q58= | Silent (SNP) | VAF 128/252 reads (51%) | catalogued as rs1555541342; called by muse, mutect2, varscan2
- IGLC2 | c.195G>A p.K65= | Silent (SNP) | VAF 28/99 reads (28%) | catalogued as rs1803804; called by muse, mutect2, varscan2
- KCNJ16 | c.735C>T p.I245= | Silent (SNP) | VAF 74/155 reads (48%) | called by muse, mutect2, varscan2
- LMAN1L | c.183C>T p.I61= | Silent (SNP) | VAF 15/29 reads (52%) | called by muse, mutect2, varscan2
- PCNX3 | c.2889G>A p.L963= | Silent (SNP) | VAF 67/140 reads (48%) | called by muse, mutect2, varscan2
- PIK3CA | c.108C>T p.C36= | Silent (SNP) | VAF 30/255 reads (12%) | called by muse, mutect2, varscan2
- PLS1 | c.1347T>C p.P449= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as rs772500647; called by muse, mutect2, varscan2
- PTPRZ1 | c.3495T>A p.T1165= | Silent (SNP) | VAF 118/245 reads (48%) | called by muse, mutect2, varscan2
- SLC25A27 | c.45G>A p.Q15= | Silent (SNP) | VAF 78/216 reads (36%) | catalogued as COSV99242351; called by muse, mutect2, varscan2
- SLC29A3 | c.684C>T p.N228= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as rs779405998; called by muse, mutect2, varscan2
- SLC46A1 | c.462C>T p.L154= | Silent (SNP) | VAF 71/145 reads (49%) | catalogued as rs782480845; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCHH | c.2706A>G p.E902= | Silent (SNP) | VAF 88/324 reads (27%) | called by muse, mutect2, varscan2
- TCL1A | c.246A>G p.G82= | Silent (SNP) | VAF 54/87 reads (62%) | called by muse, mutect2, varscan2
- TTN | c.57585A>G p.R19195= (on ENST00000591111; = p.R11771= on NM_003319.4) | Silent (SNP) | VAF 90/303 reads (30%) | called by muse, mutect2, varscan2
- TTN | c.20907C>T p.I6969= (on ENST00000591111; = p.I6042= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 129/249 reads (52%) | catalogued as COSV100625347; called by muse, mutect2, varscan2
- ADCY1 | c.*2303G>A | 3'UTR (SNP) | VAF 31/67 reads (46%) | called by muse, mutect2, varscan2
- AK9 | c.3633+13del | Intron (DEL) | VAF 6/57 reads (11%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2
- ALKBH6 | c.453+160A>T | Intron (SNP) | VAF 39/67 reads (58%) | called by muse, mutect2, varscan2
- ARHGEF3 | c.*789C>T | 3'UTR (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- ATP5MPL | c.148+322A>T | Intron (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- CCDC57 | c.619-42_619-41del | Intron (DEL) | VAF 24/69 reads (35%) | called by mutect2, pindel, varscan2
- CDH20 | c.*691G>T | 3'UTR (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2, varscan2
- CSTF2T | c.*357T>C | 3'UTR (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2, varscan2
- DNM1P46 | chr15:99807855 C>T | 5'Flank (SNP) | VAF 30/86 reads (35%) | called by muse, mutect2, varscan2
- EVX2 | c.*948G>C | 3'UTR (SNP) | VAF 44/110 reads (40%) | called by muse, mutect2, varscan2
- FAM122B | c.*150C>T | 3'UTR (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
- FAM90A27P | n.1337G>T | RNA (SNP) | VAF 7/20 reads (35%) | catalogued as rs1364751780; called by muse, mutect2
- FCGR2A | c.*406T>A | 3'UTR (SNP) | VAF 20/557 reads (4%) | called by muse, mutect2
- FKBP6 | c.57+34T>A | Intron (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2, varscan2
- GPRIN3 | c.*2767T>G | 3'UTR (SNP) | VAF 4/92 reads (4%) | called by muse, mutect2
- HPGDS | c.*233A>C | 3'UTR (SNP) | VAF 20/69 reads (29%) | called by muse, mutect2, varscan2
- IGLV1-44 | c.-29A>C | 5'UTR (SNP) | VAF 36/81 reads (44%) | called by muse, varscan2
- KDM5B | c.-86G>C | 5'UTR (SNP) | VAF 150/230 reads (65%) | called by muse, mutect2, varscan2
- KHDC4 | c.*848T>G | 3'UTR (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- KIF13A | c.*31C>T | 3'UTR (SNP) | VAF 18/246 reads (7%) | called by muse, mutect2
- LNX1 | c.979-26C>T | Intron (SNP) | VAF 13/32 reads (41%) | catalogued as rs770112996; called by muse, mutect2, varscan2
- LTB | c.163-78G>T | Intron (SNP) | VAF 225/405 reads (56%) | catalogued as COSV53002650; called by muse, mutect2, varscan2
- MSI2 | c.312+23749T>C | Intron (SNP) | VAF 33/65 reads (51%) | called by muse, mutect2, varscan2
- PLSCR1 | c.355+53G>A | Intron (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- PRDM5 | c.*2586T>C | 3'UTR (SNP) | VAF 32/85 reads (38%) | called by muse, mutect2, varscan2
- PRICKLE2 | c.*837A>G | 3'UTR (SNP) | VAF 19/83 reads (23%) | called by muse, mutect2, varscan2
- PRR13 | c.19+160dup | Intron (INS) | VAF 6/58 reads (10%) | called by mutect2, pindel
- PRRC2B | c.*963T>C | 3'UTR (SNP) | VAF 44/124 reads (35%) | called by muse, mutect2
- RABGGTB | c.*54A>G | 3'UTR (SNP) | VAF 20/124 reads (16%) | called by muse, mutect2, varscan2
- RHPN2P1 | n.782G>C | RNA (SNP) | VAF 162/517 reads (31%) | called by muse, mutect2, varscan2
- SHROOM3 | c.3753+180T>A | Intron (SNP) | VAF 90/174 reads (52%) | called by muse, mutect2, varscan2
- SLC16A1 | c.*674T>C | 3'UTR (SNP) | VAF 42/98 reads (43%) | called by muse, mutect2, varscan2
- SLC5A11 | c.*31T>C | 3'UTR (SNP) | VAF 126/276 reads (46%) | called by muse, mutect2, varscan2
- SRI | chr7:88202252 A>T | 3'Flank (SNP) | VAF 35/79 reads (44%) | called by muse, mutect2, varscan2
- STON2 | c.2784+2530C>T | Intron (SNP) | VAF 37/76 reads (49%) | called by muse, mutect2, varscan2
- SZRD1 | chr1:16367184 C>T | 5'Flank (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- TEDDM1 | c.-35A>G | 5'UTR (SNP) | VAF 45/123 reads (37%) | called by muse, mutect2, varscan2
- TTBK1 | c.*1653C>G | 3'UTR (SNP) | VAF 49/107 reads (46%) | called by muse, mutect2, varscan2
- ZDHHC3 | c.*10769G>A | 3'UTR (SNP) | VAF 129/244 reads (53%) | called by muse, mutect2, varscan2
- ZNF513 | c.-161G>A | 5'UTR (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
- ZNFX1 | chr20:49280386 C>T | 5'Flank (SNP) | VAF 25/65 reads (38%) | called by muse, mutect2, varscan2
